Somatic mutation profile of tumor specimen C3N-01219-03 (aliquot CPT0076160006) from CPTAC case C3N-01219, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G3; Age at diagnosis: 58.6 years (21,421 days).
Specimen C3N-01219-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41073041-217f-4f49-99c7-395d3e70c330.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01219-71 (Blood Derived Normal), aliquot CPT0076220002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/060684c1-8558-4adb-b726-3b1b5e7a9533

The open-access MAF lists 876 somatic variants for this specimen: 572 protein-altering or splice-affecting, 189 silent, 115 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 367, Silent 189, Frame Shift Del 117, Intron 52, Frame Shift Ins 29, 3'UTR 23, Nonsense Mutation 23, Splice Site 16, 5'UTR 13, RNA 13, In Frame Del 10, 5'Flank 7.

Variants (750 of 876; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A1 | c.3008del p.P1003Lfs*105 | Frame Shift Del (DEL) | VAF 40/165 reads (24%) | catalogued as rs72653168, CD063483; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DYRK1A | c.344del p.K115Rfs*35 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as rs1555980192; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FGFR1 | c.1636A>G p.N546D (on ENST00000447712 / NM_023110.3; = p.N544D on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/533 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519898, COSV58330676; ClinVar: likely pathogenic; called by muse, mutect2
- FOXP3 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 65/247 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1557115786, CM086633, COSV66051279; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.1966del p.L656Cfs*274 | Frame Shift Del (DEL) | VAF 6/63 reads (10%) | catalogued as rs886042284; ClinVar: pathogenic; called by mutect2, pindel
- MAN2B1 | c.2402del p.G801Afs*4 | Frame Shift Del (DEL) | VAF 136/555 reads (25%) | catalogued as rs797044680, CM051105; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PIGO | c.2361dup p.T788Hfs*5 | Frame Shift Ins (INS) | VAF 88/363 reads (24%) | catalogued as rs770591449; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PKD2 | c.1094+1G>A p.X365_splice | Splice Site (SNP) | VAF 111/406 reads (27%) | catalogued as rs58606740, CS065606, CS1110577, COSV52940349; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PORCN | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 152/512 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs267606973, CM073269; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 161/295 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SLC2A1 | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 84/317 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs1057517822, CM083157; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.6137G>A p.S2046N | Missense Mutation (SNP) | VAF 163/636 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM154524; called by muse, mutect2, varscan2
- ABCA9 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as rs1372122909, COSV60619911; called by muse, varscan2
- ABCB8 | c.1451G>A p.R484H (on ENST00000297504 / NM_001282291.2; = p.R467H on NM_007188.5) | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs774962122; called by muse, mutect2, varscan2
- ABHD13 | c.899A>G p.D300G | Missense Mutation (SNP) | VAF 9/207 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as COSV101024255; called by muse, mutect2
- ABHD15 | c.1363A>G p.N455D | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs770347594; called by muse, mutect2, varscan2
- ACACB | c.3046G>A p.V1016I | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs759357613, COSV58146707, COSV58149636; called by muse, mutect2, varscan2
- ACAN | c.1399G>T p.A467S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.214); catalogued as rs770829348; called by muse, mutect2, varscan2
- ADAMTS13 | c.598G>A p.G200S | Missense Mutation (SNP) | VAF 50/744 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782328666, COSV63020730; called by muse, mutect2
- ADGRG4 | c.3377C>T p.T1126I | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as rs139973264; called by muse, mutect2, varscan2
- ADGRL2 | c.3674C>T p.P1225L (on ENST00000370717 / NM_001366005.1; = p.P1169L on NM_012302.4) | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs143139172; called by muse, mutect2
- AHNAK2 | c.7549G>A p.G2517R | Missense Mutation (SNP) | VAF 77/686 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs757038774, COSV60908458; called by muse, mutect2, varscan2
- AKAP10 | c.1929_1932del p.S644Tfs*12 | Frame Shift Del (DEL) | VAF 7/100 reads (7%) | catalogued as rs1253451239; called by mutect2, pindel
- ANKRD11 | c.4417_4419del p.K1473del | In Frame Del (DEL) | VAF 64/567 reads (11%) | catalogued as rs766136535; called by mutect2, pindel, varscan2
- ANO7 | c.1018G>A p.G340R (on ENST00000274979; = p.G286R on NM_001370694.2) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759973631, COSV51471168; called by muse, mutect2, varscan2
- APIP | c.283del p.S95Afs*8 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs546686089; called by mutect2, varscan2
- ARHGAP6 | c.2833G>A p.A945T (on ENST00000337414 / NM_013427.3; = p.A742T on NM_013423.3) | Missense Mutation (SNP) | VAF 32/578 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.048); catalogued as rs1183332901; called by muse, mutect2
- ARID1A | c.5839C>T p.Q1947* | Nonsense Mutation (SNP) | VAF 63/237 reads (27%) | catalogued as COSV61380856; called by muse, varscan2
- ARID3C | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs757346189; called by muse, mutect2
- ASB2 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1315342522, COSV104411579; called by muse, mutect2, varscan2
- ASCL1 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 90/341 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57151956; called by muse, mutect2, varscan2
- ASTN2 | c.1256G>A p.R419H (on ENST00000313400 / NM_001365069.1; = p.R368H on NM_014010.5) | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as rs369593338, COSV57816134; called by muse, mutect2, varscan2
- ATG2A | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs765501397, COSV65966464; called by muse, mutect2
- ATP13A2 | c.2894C>T p.A965V | Missense Mutation (SNP) | VAF 33/673 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs894388775; called by muse, mutect2
- ATP8B3 | c.758T>C p.M253T | Missense Mutation (SNP) | VAF 57/263 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs760831845; called by muse, mutect2, varscan2
- ATRX | c.6236G>A p.R2079Q | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV64883229; called by muse, mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 28/78 reads (36%) | catalogued as rs1288664341; called by mutect2, pindel
- B3GALT6 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs1284101388; called by muse, mutect2, varscan2
- BAIAP3 | c.2608G>A p.D870N | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs540251081, COSV50106095; called by muse, mutect2
- BAZ1A | c.3277C>T p.R1093W | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62410159; called by muse, mutect2, varscan2
- BCL2L10 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 41/140 reads (29%) | catalogued as rs756991240, COSV53064528; called by muse, mutect2, varscan2
- BCOR | c.4258G>A p.D1420N (on ENST00000378444 / NM_001123385.2; = p.D1386N on NM_017745.6) | Missense Mutation (SNP) | VAF 52/792 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.517); catalogued as rs886042813; ClinVar: uncertain significance; called by muse, mutect2
- BDH1 | c.685del p.L229Wfs*3 | Frame Shift Del (DEL) | VAF 44/374 reads (12%) | catalogued as rs1002260866; called by mutect2, pindel, varscan2
- BMP7 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 246/621 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as rs761758732; called by muse, mutect2, varscan2
- BOD1L1 | c.6590C>T p.A2197V | Missense Mutation (SNP) | VAF 54/213 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs755143500, COSV50045089; called by muse, mutect2, varscan2
- BSCL2 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 178/669 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs1458232816, COSV54016075; called by muse, mutect2, varscan2
- C1QTNF6 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 80/360 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs749960126; called by muse, mutect2, varscan2
- CACNA1G | c.1750G>A p.V584M | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs781383568; called by muse, mutect2
- CASP1 | c.614del p.N205Ifs*7 (on ENST00000436863 / NM_033292.4; = p.N184Ifs*7 on NM_001223.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/94 reads (23%) | catalogued as rs746543598, COSV62056860; called by mutect2, varscan2
- CASQ1 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 17/248 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); catalogued as COSV100927277; called by muse, mutect2
- CASS4 | c.1447A>G p.T483A | Missense Mutation (SNP) | VAF 22/388 reads (6%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1178020023; called by muse, mutect2
- CATSPERB | c.274A>G p.T92A | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1279488578; called by muse, mutect2, varscan2
- CCDC142 | c.1592G>A p.R531Q (on ENST00000393965 / NM_001365575.2; = p.R524Q on NM_032779.4) | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs141691625; called by muse, mutect2, varscan2
- CCDC168 | c.21051del p.F7017Lfs*25 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs397851855; called by mutect2, varscan2
- CCR3 | c.701del p.K234Sfs*52 | Frame Shift Del (DEL) | VAF 36/148 reads (24%) | catalogued as rs761073142; called by mutect2, varscan2
- CDH4 | c.1781del p.P594Rfs*35 | Frame Shift Del (DEL) | VAF 30/232 reads (13%) | catalogued as rs1367432489; called by mutect2, pindel
- CEP295 | c.463C>T p.L155F | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.733); catalogued as rs1189370355; called by muse, mutect2, varscan2
- CEP295 | c.1657dup p.T553Nfs*18 | Frame Shift Ins (INS) | VAF 23/100 reads (23%) | catalogued as rs749718914; called by mutect2, varscan2
- CEP85 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs778329650; called by muse, mutect2
- CERK | c.1489A>C p.S497R | Missense Mutation (SNP) | VAF 83/346 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.404); catalogued as COSV53453692; called by muse, mutect2, varscan2
- CFAP161 | c.832A>G p.M278V | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as rs1392612418; called by muse, mutect2, varscan2
- CFAP61 | c.1823T>C p.L608P | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776620594; called by muse, mutect2, varscan2
- CHP1 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58157819; called by muse, mutect2
- CHRDL1 | c.721C>T p.Q241* (on ENST00000372045; = p.Q247* on NM_145234.4) | Nonsense Mutation (SNP) | VAF 10/217 reads (5%) | catalogued as COSV54326021; called by muse, mutect2
- CHRDL2 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs756278232, COSV99733987; called by muse, mutect2, varscan2
- CHST12 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs1196946734, COSV51673995, COSV51675495; called by muse, mutect2, varscan2
- CLOCK | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 58/282 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59405091; called by muse, mutect2, varscan2
- CPLX1 | c.329A>T p.E110V | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58377007; called by muse, mutect2, varscan2
- CROCC | c.3386C>T p.A1129V | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs573098773; called by muse, mutect2, varscan2
- CTSH | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 84/302 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs201782561, COSV54985005; called by muse, mutect2, varscan2
- CTSV | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 37/407 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs566025108, COSV52344646; called by muse, mutect2
- CYB561 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 22/332 reads (7%) | catalogued as rs1198810545; called by muse, mutect2
- CYP4F12 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 72/268 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV61175570; called by muse, mutect2, varscan2
- DEDD | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 136/295 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.898); catalogued as rs748758614, COSV63502472; called by muse, mutect2, varscan2
- DEPDC5 | c.2728C>T p.R910C (on ENST00000400246; = p.R979C on NM_014662.5) | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56709488; called by muse, mutect2
- DNAH1 | c.6776G>A p.R2259H | Missense Mutation (SNP) | VAF 84/364 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs780533738, COSV70230950; called by muse, mutect2, varscan2
- DOHH | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.474); catalogued as rs1337457335; called by muse, mutect2, varscan2
- DOK2 | c.1016C>A p.P339H | Missense Mutation (SNP) | VAF 98/340 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs779421891; called by muse, mutect2, varscan2
- DSE | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763556352; called by muse, mutect2, varscan2
- DSN1 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 51/324 reads (16%) | catalogued as rs73105200, COSV104425052; called by muse, mutect2, varscan2
- DSP | c.4387G>A p.V1463I | Missense Mutation (SNP) | VAF 188/633 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs948230523, COSV65791255; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DVL3 | c.2015C>T p.P672L | Missense Mutation (SNP) | VAF 43/258 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs753752963; called by muse, mutect2, varscan2
- DYNC1H1 | c.12293A>C p.N4098T | Missense Mutation (SNP) | VAF 47/838 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64136864; called by muse, mutect2
- DYNC2I2 | c.1340G>T p.R447L | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as CM1311171; called by muse, mutect2
- DYRK1B | c.1177del p.E393Sfs*110 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as rs1270847383; called by mutect2, pindel, varscan2
- ECE1 | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); catalogued as rs1217585537; called by muse, mutect2
- EPB41L1 | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 93/370 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs780638341, COSV99151434; called by muse, mutect2, varscan2
- EPC2 | c.1006_1008del p.K336del | In Frame Del (DEL) | VAF 38/102 reads (37%) | catalogued as rs748355974; called by pindel, varscan2
- EPHA8 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1391875727, COSV51272925, COSV99384177; called by muse, mutect2
- EPPK1 | c.4432G>A p.V1478I | Missense Mutation (SNP) | VAF 67/303 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.014); catalogued as rs201602383; called by muse, mutect2, varscan2
- ERAS | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs782373989, COSV54433255; called by muse, mutect2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 26/79 reads (33%) | catalogued as rs753821453; called by mutect2, varscan2
- ERN1 | c.2801C>T p.T934I | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); catalogued as COSV101458370; called by muse, mutect2, varscan2
- ESPNL | c.823del p.L275Sfs*16 | Frame Shift Del (DEL) | VAF 46/162 reads (28%) | catalogued as rs1309653898; called by mutect2, pindel, varscan2
- EVC2 | c.844dup p.S282Ffs*59 | Frame Shift Ins (INS) | VAF 97/442 reads (22%) | catalogued as rs1168765379; called by mutect2, pindel, varscan2
- EVX1 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 26/498 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.217); catalogued as COSV99763944; called by muse, mutect2
- F10 | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 224/795 reads (28%) | catalogued as COSV65020905, COSV65023449; called by muse, mutect2, varscan2
- FAM181A | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs768244942; called by muse, mutect2
- FAT1 | c.12754C>T p.R4252W | Missense Mutation (SNP) | VAF 61/284 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759440990; called by muse, mutect2, varscan2
- FBXL19 | c.1922C>T p.T641M | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1376354164; called by muse, mutect2
- FGF13 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as rs758308695; called by muse, mutect2, varscan2
- FIBP | c.290A>G p.Y97C | Missense Mutation (SNP) | VAF 23/368 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs901218694; called by muse, mutect2
- FLT4 | c.2851_2853del p.E951del | In Frame Del (DEL) | VAF 74/331 reads (22%) | catalogued as rs746341092; called by mutect2, pindel, varscan2
- FOXJ1 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs532386546; called by muse, mutect2, varscan2
- FOXK1 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61066683; called by muse, mutect2
- FSIP2 | c.1454C>A p.P485H | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV58078937; called by muse, mutect2, varscan2
- FXR1 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); catalogued as COSV59763012; called by muse, mutect2, varscan2
- GABRG3 | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61519612; called by muse, mutect2, varscan2
- GAS6 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT tolerated (0.99); PolyPhen benign (0.277); catalogued as rs146140804; called by muse, mutect2, varscan2
- GDF7 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as rs1017294631; called by muse, mutect2, varscan2
- GOLGA6L1 | c.1663del p.E555Sfs*19 | Frame Shift Del (DEL) | VAF 70/758 reads (9%) | catalogued as rs1466221361; called by pindel, varscan2
- GPR12 | c.956G>A p.C319Y | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67343960; called by muse, mutect2, varscan2
- GPR45 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 55/278 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as rs202232782; called by muse, mutect2, varscan2
- GRID2IP | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 33/296 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs1354691880; called by muse, mutect2, varscan2
- GRIN2D | c.1861+1G>A p.X621_splice | Splice Site (SNP) | VAF 10/86 reads (12%) | catalogued as COSV54378422; called by muse, mutect2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 28/124 reads (23%) | catalogued as rs754199513; called by mutect2, varscan2
- HAND2 | c.168del p.D57Tfs*42 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | catalogued as rs763941066, COSV100854267; called by mutect2, pindel, varscan2
- HCFC1 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.304); catalogued as COSV60073046; called by muse, mutect2
- HEMK1 | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759933907, COSV51751880, COSV99231535; called by muse, mutect2, varscan2
- HEPHL1 | c.1666G>T p.G556W | Missense Mutation (SNP) | VAF 77/280 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59890251; called by muse, mutect2, varscan2
- HERC2 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs547492310, COSV55341953; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.7-3del | Splice Region (DEL) | VAF 18/47 reads (38%) | catalogued as rs759915055; called by mutect2, pindel
- HS3ST6 | c.1018G>A p.G340S | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as rs780340724; called by muse, mutect2, varscan2
- HTR3E | c.833G>A p.R278H (on ENST00000415389 / NM_001256613.1; = p.R293H on NM_182589.2) | Missense Mutation (SNP) | VAF 147/468 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.14); catalogued as rs1444444517; called by muse, mutect2, varscan2
- IGF2BP1 | c.1555G>C p.A519P | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51731658; called by muse, mutect2, varscan2
- IL17RD | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs1486656267; called by muse, mutect2
- INPPL1 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 67/315 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753557940, COSV53360469; called by muse, mutect2, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 22/78 reads (28%) | catalogued as rs1561359523; called by mutect2, varscan2
- KANSL1 | c.611del p.G204Vfs*2 | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | catalogued as rs1304078301; called by mutect2, pindel, varscan2
- KATNB1 | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.394); catalogued as rs781977681; called by muse, mutect2, varscan2
- KCNJ12 | c.214T>G p.F72V | Missense Mutation (SNP) | VAF 82/1385 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59165360; called by muse, mutect2
- KCNN3 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV55215732; called by muse, mutect2
- KDM2B | c.1734+7C>T | Splice Region (SNP) | VAF 17/189 reads (9%) | catalogued as rs61757389; called by muse, mutect2
- KIF26A | c.3440del p.P1147Lfs*101 | Frame Shift Del (DEL) | VAF 45/126 reads (36%) | catalogued as rs771825279; called by mutect2, pindel, varscan2
- KIF3B | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as rs372791961; called by muse, mutect2, varscan2
- KLHL10 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53173114; called by muse, mutect2
- KLHL31 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1333004367, COSV100911781; called by muse, mutect2, varscan2
- KMT2D | c.231del p.H77Qfs*53 | Frame Shift Del (DEL) | VAF 30/302 reads (10%) | catalogued as COSV56471398, COSV99980400; called by mutect2, pindel
- KRT72 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as rs1397888281; called by muse, mutect2, varscan2
- L3MBTL1 | c.361-7G>A | Splice Region (SNP) | VAF 103/285 reads (36%) | catalogued as rs200054978, COSV100917183, COSV64235017; called by muse, mutect2, varscan2
- LAMP1 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 62/297 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs370862051; called by muse, mutect2, varscan2
- LEPR | c.3268_3269dup p.S1090Rfs*6 | Frame Shift Ins (INS) | VAF 16/106 reads (15%) | catalogued as rs1553174844; called by mutect2, varscan2
- LINC01588 | n.3998del | Splice Region (DEL) | VAF 76/247 reads (31%) | catalogued as rs1566762142; called by mutect2, pindel, varscan2
- LMO7 | c.985G>A p.A329T (on ENST00000357063; = p.A344T on NM_005358.5) | Missense Mutation (SNP) | VAF 54/220 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as rs759287235, COSV100414016; called by muse, mutect2, varscan2
- LMOD2 | c.1443del p.K484Rfs*10 | Frame Shift Del (DEL) | VAF 30/138 reads (22%) | catalogued as COSV71755857; called by mutect2, pindel, varscan2
- LOXHD1 | c.2839G>A p.D947N | Missense Mutation (SNP) | VAF 85/783 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs371808826, COSV56062529; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRFN4 | c.1571del p.G524Vfs*100 | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | catalogued as COSV100540885; called by mutect2, pindel, varscan2
- LRIG3 | c.359C>A p.S120* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as COSV57865247; called by muse, varscan2
- LRPAP1 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as rs751267591, COSV104407652; called by muse, mutect2, varscan2
- LRRFIP1 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as rs1016540610; called by muse, mutect2, varscan2
- LRRK1 | c.5743G>A p.V1915I | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as rs775588013, COSV52628754; called by muse, mutect2, varscan2
- LTB4R | c.1006C>A p.P336T | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs1354963283; called by muse, mutect2, varscan2
- LTBP1 | c.4774G>A p.A1592T (on ENST00000404816 / NM_206943.4; = p.A1266T on NM_000627.4) | Missense Mutation (SNP) | VAF 72/284 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.836); catalogued as rs780408176; called by muse, mutect2, varscan2
- LTBP3 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 172/643 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.119); catalogued as rs1199471046, COSV100100407; called by muse, mutect2, varscan2
- MANEA | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as rs945118080, COSV62589378; called by muse, mutect2, varscan2
- MAPK8IP1 | c.2050G>A p.A684T | Missense Mutation (SNP) | VAF 21/587 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1187812564; called by muse, mutect2
- MAST1 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 87/377 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs144422287; called by muse, mutect2, varscan2
- MAST4 | c.5432C>T p.S1811F (on ENST00000403625 / NM_001164664.2; = p.S1622F on NM_015183.3) | Missense Mutation (SNP) | VAF 13/332 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55124484; called by muse, mutect2
- MAX | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 30/617 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52416276, COSV52416985, COSV52418829; called by muse, mutect2
- MAX | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 36/615 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV52419294; called by muse, mutect2
- MCM10 | c.940del p.T314Pfs*7 (on ENST00000484800 / NM_182751.3; = p.T313Pfs*7 on NM_018518.5) | Frame Shift Del (DEL) | VAF 25/84 reads (30%) | catalogued as COSV66333281; called by mutect2, pindel, varscan2
- MEX3D | c.1726del p.L576Wfs*33 | Frame Shift Del (DEL) | VAF 24/86 reads (28%) | catalogued as rs1487685986; called by mutect2, pindel, varscan2
- MIGA2 | c.226G>T p.G76C | Missense Mutation (SNP) | VAF 101/453 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs768879690; called by muse, mutect2, varscan2
- MMP21 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.107); catalogued as COSV64289758; called by muse, mutect2, varscan2
- MRPL3 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs780745879; called by muse, mutect2, varscan2
- MTCL1 | c.3910C>T p.R1304C (on ENST00000306329 / NM_001378206.1; = p.R985C on NM_015210.4) | Missense Mutation (SNP) | VAF 28/507 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs1240061406, COSV60411478; called by muse, mutect2
- MTMR14 | c.1622A>G p.D541G | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.411); catalogued as COSV56004141; called by muse, mutect2, varscan2
- MTSS1 | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780128073, COSV52674192; called by muse, mutect2
- MTSS2 | c.2156del p.P719Rfs*49 | Frame Shift Del (DEL) | VAF 45/144 reads (31%) | catalogued as rs1273342345, COSV55380672; called by mutect2, pindel, varscan2
- MXD3 | c.148dup p.Q50Pfs*15 | Frame Shift Ins (INS) | VAF 12/50 reads (24%) | catalogued as rs866699857; called by mutect2, varscan2
- MYO10 | c.3709C>T p.R1237C | Missense Mutation (SNP) | VAF 100/493 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1056851431, COSV57018034; called by muse, mutect2, varscan2
- NAALADL1 | c.723dup p.S242Lfs*56 | Frame Shift Ins (INS) | VAF 114/472 reads (24%) | catalogued as rs761671591; called by mutect2, pindel, varscan2
- NCBP2 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 47/227 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762320814; called by muse, mutect2, varscan2
- NIPA1 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 119/483 reads (25%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as rs758889619, COSV61679635; called by muse, mutect2, varscan2
- NLRX1 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 20/342 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs746456833; called by muse, mutect2
- NOC2L | c.1388C>T p.T463M | Missense Mutation (SNP) | VAF 77/386 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs563697611, COSV58989724; called by mutect2, varscan2
- NR2C1 | c.252dup p.T85Yfs*4 | Frame Shift Ins (INS) | VAF 26/366 reads (7%) | catalogued as rs1269072542; called by mutect2, pindel
- NUP107 | c.1468G>C p.E490Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.669); catalogued as rs1341434258; called by muse, mutect2, varscan2
- OR2T27 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs760930226; called by muse, mutect2, varscan2
- OTOF | c.4768G>A p.A1590T (on ENST00000272371 / NM_194248.3; = p.A823T on NM_004802.4) | Missense Mutation (SNP) | VAF 85/328 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as rs1046534040, COSV55522083; called by muse, mutect2, varscan2
- OXER1 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 86/306 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.046); catalogued as rs771020476; called by muse, mutect2, varscan2
- PAMR1 | c.2021C>T p.P674L (on ENST00000619888 / NM_001001991.3; = p.P691L on NM_015430.4) | Missense Mutation (SNP) | VAF 103/471 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs201029324, COSV53512693; called by muse, mutect2, varscan2
- PCDHA7 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 93/403 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1359916127; called by muse, mutect2, varscan2
- PCDHB9 | c.1176del p.L393* | Frame Shift Del (DEL) | VAF 80/307 reads (26%) | catalogued as rs782200278; called by mutect2, varscan2
- PCDHGB1 | c.1928G>A p.R643H | Missense Mutation (SNP) | VAF 104/387 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as rs752131601, COSV99543974; called by muse, mutect2, varscan2
- PCDHGB6 | c.1546G>T p.A516S | Missense Mutation (SNP) | VAF 76/324 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV99531762; called by muse, mutect2, varscan2
- PCK1 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 117/276 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs536299130, COSV60126231; called by muse, mutect2, varscan2
- PDZD4 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 58/261 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557076928, COSV51245450; called by muse, mutect2, varscan2
- PGBD5 | c.445G>A p.V149M (on ENST00000525115; = p.V218M on NM_001258311.2) | Missense Mutation (SNP) | VAF 42/340 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV58410683; called by muse, mutect2, varscan2
- PIK3R2 | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 59/331 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as rs772782368, COSV55850116; called by muse, mutect2, varscan2
- PIP5K1C | c.1615T>C p.S539P | Missense Mutation (SNP) | VAF 132/486 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as rs79423827; called by muse, varscan2
- PLCB3 | c.2827G>A p.A943T | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.087); catalogued as rs1238246666; called by muse, mutect2, varscan2
- PLCB4 | c.2770C>T p.Q924* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99597491; called by muse, mutect2, varscan2
- PLEKHO2 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs567549261, COSV60263176; called by muse, mutect2, varscan2
- PLPPR3 | c.1015G>A p.V339M (on ENST00000520876 / NM_001270366.2; = p.V367M on NM_024888.2) | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.489); catalogued as rs1178637656; called by muse, mutect2
- PLXNA4 | c.4147C>T p.R1383C | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs888077375; called by muse, mutect2
- PLXNB1 | c.536del p.G179Vfs*41 | Frame Shift Del (DEL) | VAF 21/70 reads (30%) | catalogued as rs953293505; called by mutect2, pindel, varscan2
- PLXNB2 | c.1690C>A p.P564T | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1476539274; called by muse, mutect2
- POGZ | c.2195del p.P732Lfs*14 | Frame Shift Del (DEL) | VAF 8/95 reads (8%) | catalogued as COSV55042562; called by mutect2, pindel
- POLR1A | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as rs1420946469; called by muse, mutect2, varscan2
- PPOX | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 146/294 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as CM031719, COSV57086831, COSV99237149; called by muse, varscan2
- PPP1R9B | c.1060_1062del p.K354del | In Frame Del (DEL) | VAF 40/178 reads (22%) | catalogued as rs1340845687; called by mutect2, pindel, varscan2
- PPP6C | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 93/394 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV65208478; called by muse, mutect2, varscan2
- PREX1 | c.3151G>A p.G1051R | Missense Mutation (SNP) | VAF 22/555 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.123); catalogued as rs1024320477, COSV64250192; called by muse, mutect2
- PRRT4 | c.2006G>A p.R669H | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV71054711, COSV71054778; called by muse, mutect2
- PTPN21 | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); catalogued as rs749444002, COSV100161619; called by muse, mutect2, varscan2
- PTPRS | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 23/86 reads (27%) | catalogued as COSV53637133; called by muse, mutect2, varscan2
- PTX4 | c.1191del p.G398Efs*57 (on ENST00000447419 / NM_001328608.2; = p.G393Efs*57 on NM_001013658.1) | Frame Shift Del (DEL) | VAF 71/229 reads (31%) | catalogued as rs772722517, COSV99560265; called by mutect2, pindel, varscan2
- RBM25 | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); catalogued as COSV99998456; called by muse, mutect2, varscan2
- RBM33 | c.3137C>T p.P1046L | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.443); catalogued as rs1486467453; called by muse, mutect2, varscan2
- RBMXL3 | c.2680C>T p.R894C | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.527); catalogued as rs977979063; called by muse, mutect2
- RNF213 | c.13537G>A p.V4513M | Missense Mutation (SNP) | VAF 25/403 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs148541222; called by muse, mutect2
- RNF6 | c.1778del p.L593Yfs*2 | Frame Shift Del (DEL) | VAF 42/185 reads (23%) | catalogued as rs1199638878, COSV60419447; called by mutect2, varscan2
- RRAGA | c.183G>T p.W61C | Missense Mutation (SNP) | VAF 73/260 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65844130; called by muse, mutect2, varscan2
- RUSC1 | c.1062dup p.S355Lfs*101 | Frame Shift Ins (INS) | VAF 50/124 reads (40%) | catalogued as rs771809865; called by mutect2, varscan2
- SAFB2 | c.2471del p.G824Afs*8 | Frame Shift Del (DEL) | VAF 34/150 reads (23%) | catalogued as rs759920279; called by mutect2, pindel, varscan2
- SAMD14 | c.855del p.S286Afs*67 (on ENST00000330175 / NM_001257359.2; = p.S314Afs*67 on NM_174920.4) | Frame Shift Del (DEL) | VAF 22/200 reads (11%) | catalogued as rs1567718169; called by mutect2, pindel, varscan2
- SDK1 | c.5930G>A p.R1977Q | Missense Mutation (SNP) | VAF 120/218 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs776142639; called by muse, mutect2, varscan2
- SELENBP1 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 21/310 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs541709868, COSV64372956; called by muse, mutect2
- SEMA3F | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1300931462, COSV50030215; called by muse, mutect2
- SETD1B | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs924900033; called by muse, mutect2, varscan2
- SETDB2 | c.1516del p.M506Wfs*24 | Frame Shift Del (DEL) | VAF 22/100 reads (22%) | catalogued as rs768645211; called by mutect2, pindel, varscan2
- SF3B4 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.147); catalogued as COSV99641423; called by muse, mutect2, varscan2
- SLC22A24 | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as rs767638731; called by muse, varscan2
- SLC25A13 | c.1274C>T p.S425L | Missense Mutation (SNP) | VAF 50/496 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.166); catalogued as rs1403481477, COSV55708127; called by muse, mutect2, varscan2
- SLC25A29 | c.479G>A p.R160H (on ENST00000359232 / NM_001039355.3; = p.R94H on NM_152333.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/294 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766435527, COSV63650328; called by muse, mutect2, varscan2
- SLC26A1 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs766926909, COSV56102281; called by muse, mutect2, varscan2
- SLC38A8 | c.388+1G>A p.X130_splice | Splice Site (SNP) | VAF 74/250 reads (30%) | catalogued as rs149436446; called by muse, mutect2, varscan2
- SLC45A1 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 33/305 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs574598878, COSV57093836; called by muse, mutect2, varscan2
- SLC52A1 | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.53); catalogued as rs755105402; called by muse, mutect2, varscan2
- SLC7A2 | c.1219C>A p.L407M (on ENST00000494857 / NM_001370338.1; = p.L446M on NM_003046.6) | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1465806851; called by muse, varscan2
- SMAD9 | c.35_37del p.S12del | In Frame Del (DEL) | VAF 79/267 reads (30%) | catalogued as rs749803590; called by mutect2, pindel, varscan2
- SMAP1 | c.613del p.S205Vfs*15 (on ENST00000370455 / NM_001044305.3; = p.S178Vfs*15 on NM_021940.5) | Frame Shift Del (DEL) | VAF 45/148 reads (30%) | catalogued as rs766085867, COSV100391091; called by mutect2, varscan2
- SMC6 | c.1228del p.I410Yfs*4 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | catalogued as rs760667210; called by mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 36/182 reads (20%) | catalogued as rs768873484; called by mutect2, varscan2
- SNX7 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 90/362 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373205340; called by muse, mutect2, varscan2
- SPATA31A3 | c.1930C>T p.Q644* | Nonsense Mutation (SNP) | VAF 17/792 reads (2%) | catalogued as rs1314925420; called by muse, mutect2
- SPOP | c.361C>G p.R121G | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV61653397, COSV61655511; called by muse, varscan2
- SPSB1 | c.370del p.L124Cfs*56 | Frame Shift Del (DEL) | VAF 27/115 reads (23%) | catalogued as COSV60165026; called by mutect2, pindel, varscan2
- ST14 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 73/252 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs147508411, COSV99598941; called by muse, mutect2, varscan2
- STAG1 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs757393709, COSV52600654; called by muse, mutect2, varscan2
- STARD13 | c.2572G>A p.A858T (on ENST00000336934 / NM_001243476.3; = p.A740T on NM_052851.3) | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.72); catalogued as rs753159681; called by muse, mutect2, varscan2
- SYVN1 | c.1810C>T p.R604C (on ENST00000377190 / NM_172230.3; = p.R603C on NM_032431.3) | Missense Mutation (SNP) | VAF 67/262 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs768364691; called by muse, mutect2, varscan2
- SYVN1 | c.1604G>A p.R535Q (on ENST00000377190 / NM_172230.3; = p.R534Q on NM_032431.3) | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.885); catalogued as rs770266350; called by muse, mutect2, varscan2
- TBX4 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs951749304, COSV53607641; called by muse, mutect2, varscan2
- TBXAS1 | c.1571del p.N524Mfs*29 | Frame Shift Del (DEL) | VAF 68/527 reads (13%) | catalogued as rs748691839; called by mutect2, pindel, varscan2
- TDRD7 | c.958C>A p.P320T | Missense Mutation (SNP) | VAF 110/456 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV100795834; called by muse, mutect2, varscan2
- TECRL | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs779934093, COSV67086444, COSV67089614; called by muse, mutect2
- TENM2 | c.5497A>G p.T1833A (on ENST00000518659 / NM_001122679.2; = p.T1594A on NM_001080428.3) | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.23); catalogued as rs1482473060; called by muse, mutect2, varscan2
- TEX264 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1372292240, COSV56584715; called by muse, mutect2
- TFDP2 | c.1226G>A p.S409N (on ENST00000489671 / NM_001178139.2; = p.S349N on NM_006286.5) | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV57712013; called by muse, mutect2, varscan2
- TLE1 | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100918842, COSV64720352; called by muse, mutect2
- TMEM156 | c.41T>C p.V14A | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV60744346; called by muse, mutect2, varscan2
- TMEM185B | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 114/363 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101446794; called by muse, mutect2, varscan2
- TMEM253 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs1381586181, COSV100711766; called by muse, mutect2
- TNF | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs548532642, COSV69304161; called by muse, mutect2, varscan2
- TNRC18 | c.4627del p.R1543Afs*13 | Frame Shift Del (DEL) | VAF 65/133 reads (49%) | catalogued as rs754233336; called by mutect2, pindel, varscan2
- TRMT13 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1373317962; called by muse, mutect2, varscan2
- TRUB1 | c.595dup p.L199Pfs*20 | Frame Shift Ins (INS) | VAF 11/43 reads (26%) | catalogued as rs762997509; called by mutect2, varscan2
- TTC3 | c.1573del p.I525* | Frame Shift Del (DEL) | VAF 39/158 reads (25%) | catalogued as rs759525538; called by mutect2, pindel, varscan2
- TTN | c.102416G>A p.R34139H (on ENST00000591111; = p.R26715H on NM_003319.4) | Missense Mutation (SNP) | VAF 31/113 reads (27%) | PolyPhen benign (0); catalogued as rs770904787, COSV100603854; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.100568G>A p.R33523H (on ENST00000591111; = p.R26099H on NM_003319.4) | Missense Mutation (SNP) | VAF 108/383 reads (28%) | PolyPhen benign (0.003); catalogued as rs768358201; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TXNDC5 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774141492, COSV65730278; called by muse, mutect2, varscan2
- UBA1 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 155/519 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs1556786387; called by muse, mutect2, varscan2
- UNKL | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 22/257 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as rs548556096, COSV57019235; called by muse, mutect2
- USP10 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 65/319 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as rs1265922762, COSV54748721; called by muse, mutect2, varscan2
- USP53 | c.2186C>T p.T729M | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs373810223; called by muse, mutect2, varscan2
- VILL | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 134/467 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1180343561; called by muse, mutect2, varscan2
- VPS8 | c.1643G>A p.R548Q (on ENST00000625842 / NM_001349294.1; = p.R546Q on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as rs752593630, COSV54980422; called by muse, varscan2
- VWA2 | c.1886G>A p.R629Q | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs371230333; called by muse, mutect2, varscan2
- WDR27 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs190339321; called by muse, mutect2, varscan2
- WDR81 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs1315630585; called by muse, mutect2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 50/177 reads (28%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WFS1 | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 51/544 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as rs780727054; called by muse, mutect2
- WNK2 | c.3686C>T p.A1229V | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1053859316; called by muse, mutect2
- ZBTB47 | c.2218G>T p.G740C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.262); catalogued as rs1340297466; called by muse, mutect2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 56/240 reads (23%) | catalogued as rs745875253; called by mutect2, varscan2
- ZMYM4 | c.1290del p.K430Nfs*6 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs755663477, COSV58913572; called by mutect2, varscan2
- ZNF8 | c.1642C>T p.Q548* | Nonsense Mutation (SNP) | VAF 17/206 reads (8%) | catalogued as rs772234021; called by muse, mutect2
- ZNF850 | c.791C>A p.P264Q | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs377231192; called by muse, mutect2, varscan2
- ZNRF3 | c.1838C>T p.S613L (on ENST00000544604 / NM_001206998.2; = p.S513L on NM_032173.3) | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.048); catalogued as rs1191064103; called by muse, mutect2, varscan2
- ZSCAN5A | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as rs774809636, COSV54226697; called by muse, mutect2, varscan2
- ABCA4 | c.5714G>T p.W1905L | Missense Mutation (SNP) | VAF 24/584 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.177); called by muse, mutect2
- ABCC11 | c.2867G>A p.S956N | Missense Mutation (SNP) | VAF 105/381 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- ABCC2 | c.3097G>T p.A1033S | Missense Mutation (SNP) | VAF 29/468 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0.007); called by muse, mutect2
- ABR | c.1844T>C p.M615T (on ENST00000302538 / NM_021962.5; = p.M578T on NM_001092.5) | Missense Mutation (SNP) | VAF 21/314 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- ACAA1 | c.1088del p.P363Lfs*4 | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | called by mutect2, pindel, varscan2
- ADAMTS12 | c.1658A>G p.H553R | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- ADGB | c.246del p.F82Lfs*14 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | called by mutect2, pindel, varscan2
- AGO2 | c.1375del p.Q459Sfs*9 | Frame Shift Del (DEL) | VAF 18/95 reads (19%) | called by mutect2, pindel
- AIRE | c.929G>A p.C310Y | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AJM1 | c.2114C>T p.A705V | Missense Mutation (SNP) | VAF 14/215 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- ALDH9A1 | c.124del p.A42Pfs*22 | Frame Shift Del (DEL) | VAF 26/244 reads (11%) | called by mutect2, pindel
- ARFGEF3 | c.4095G>T p.L1365= | Splice Region (SNP) | VAF 34/168 reads (20%) | called by muse, mutect2, varscan2
- ARHGAP4 | c.236G>A p.G79D | Missense Mutation (SNP) | VAF 99/344 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ARHGEF10 | c.1660A>G p.T554A (on ENST00000398564; = p.T529A on NM_014629.4) | Missense Mutation (SNP) | VAF 137/563 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ARID1A | c.827del p.G276Efs*87 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | called by mutect2, pindel
- ARID1A | c.5917T>C p.W1973R | Missense Mutation (SNP) | VAF 118/452 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.166); called by muse, varscan2
- ARID4A | c.2605del p.I869* | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | called by mutect2, pindel, varscan2
- ARID5B | c.1498dup p.Y500Lfs*28 | Frame Shift Ins (INS) | VAF 67/215 reads (31%) | called by mutect2, pindel, varscan2
- ARSD | c.1779del p.*594Efs*13 | Frame Shift Del (DEL) | VAF 24/91 reads (26%) | called by mutect2, pindel, varscan2
- ASAH2 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 122/441 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- ASAP1 | c.1442A>G p.H481R | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP11A | c.3191A>G p.Y1064C | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); called by muse, mutect2
- B4GALNT1 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 79/306 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BAHCC1 | c.2925del p.T976Rfs*43 | Frame Shift Del (DEL) | VAF 24/292 reads (8%) | called by mutect2, pindel
- C1QL1 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 82/307 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- C1QTNF5 | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 12/159 reads (8%) | called by muse, mutect2
- C1orf35 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 25/344 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C2CD2 | c.1888G>T p.G630C | Missense Mutation (SNP) | VAF 89/271 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- C2CD4B | c.1093T>C p.*365Rext*111 | Nonstop Mutation (SNP) | VAF 16/48 reads (33%) | called by muse, varscan2
- CAMSAP1 | c.904dup p.Y302Lfs*82 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | called by mutect2, pindel
- CAPN9 | c.1481+1G>C p.X494_splice | Splice Site (SNP) | VAF 131/226 reads (58%) | called by muse, mutect2, varscan2
- CCAR2 | c.1886del p.G629Efs*27 | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | called by mutect2, pindel, varscan2
- CCDC42 | c.860dup p.Q288Afs*40 | Frame Shift Ins (INS) | VAF 40/191 reads (21%) | called by mutect2, pindel, varscan2
- CCDC73 | c.3224del p.N1075Tfs*4 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | called by mutect2, pindel, varscan2
- CD164 | c.443_444del p.T148Sfs*14 | Frame Shift Del (DEL) | VAF 66/264 reads (25%) | called by mutect2, pindel, varscan2
- CD5L | c.948_949insT p.G317Wfs*55 | Frame Shift Ins (INS) | VAF 203/417 reads (49%) | called by mutect2, pindel, varscan2
- CD63 | c.279_281del p.I93del | In Frame Del (DEL) | VAF 36/226 reads (16%) | called by mutect2, pindel, varscan2
- CDC25C | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 16/214 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- CEL | c.427C>T p.L143F (on ENST00000673714; = p.L140F on NM_001807.6) | Missense Mutation (SNP) | VAF 130/426 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CEP350 | c.4969del p.T1657Lfs*9 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | called by mutect2, pindel
- CFAP61 | c.2001G>T p.K667N | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- CHD4 | c.380_382del p.K127del | In Frame Del (DEL) | VAF 97/342 reads (28%) | called by pindel, varscan2
- CHD7 | c.1932_1933del p.R646Vfs*29 | Frame Shift Del (DEL) | VAF 85/393 reads (22%) | called by mutect2, pindel, varscan2
- CLUL1 | c.117G>T p.E39D | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CLVS2 | c.320dup p.L108Pfs*42 | Frame Shift Ins (INS) | VAF 74/333 reads (22%) | called by mutect2, pindel, varscan2
- CNNM1 | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CNNM4 | c.1543T>C p.Y515H | Missense Mutation (SNP) | VAF 16/400 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- COL12A1 | c.3135del p.T1046Qfs*7 | Frame Shift Del (DEL) | VAF 138/534 reads (26%) | called by mutect2, pindel, varscan2
- COL24A1 | c.3491G>T p.G1164V | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COPS3 | c.531T>A p.D177E | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CPN2 | c.359T>C p.L120P | Missense Mutation (SNP) | VAF 76/241 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CRELD2 | c.490G>T p.G164W | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- CSTF2T | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 59/226 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CTNNA1 | c.2434-1G>T p.X812_splice | Splice Site (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- CYP24A1 | c.757A>G p.M253V | Missense Mutation (SNP) | VAF 188/924 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.311); called by muse, varscan2
- CYREN | c.137+2T>C p.X46_splice | Splice Site (SNP) | VAF 24/101 reads (24%) | called by muse, mutect2, varscan2
- DDAH2 | c.292C>G p.P98A | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- DDB1 | c.1483G>T p.A495S | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DIDO1 | c.3797del p.P1266Lfs*8 | Frame Shift Del (DEL) | VAF 173/479 reads (36%) | called by mutect2, pindel, varscan2
- DIP2C | c.2663C>A p.T888N | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- DNAJB5 | c.509del p.P170Qfs*21 | Frame Shift Del (DEL) | VAF 114/452 reads (25%) | called by mutect2, pindel, varscan2
- DPP7 | c.797dup p.T267Hfs*13 | Frame Shift Ins (INS) | VAF 106/455 reads (23%) | called by mutect2, pindel, varscan2
- DUXB | c.461G>T p.R154I | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- DYRK1A | c.25_27del p.A9del | In Frame Del (DEL) | VAF 10/96 reads (10%) | called by mutect2, pindel
- DYRK1A | c.1434_1442delinsAC p.F478Lfs*112 | Frame Shift Del (DEL) | VAF 34/269 reads (13%) | called by pindel, varscan2*
- DYRK1B | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 16/484 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EDN1 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 18/366 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2
- EFCAB6 | c.2204T>C p.F735S | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- EML4 | c.387dup p.E130Rfs*6 | Frame Shift Ins (INS) | VAF 22/90 reads (24%) | called by mutect2, varscan2
- EML6 | c.1158G>T p.K386N | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); called by muse, mutect2
- EOMES | c.579del p.G194Afs*94 | Frame Shift Del (DEL) | VAF 18/168 reads (11%) | called by mutect2, pindel
- EPHA3 | c.2558dup p.L853Ffs*20 | Frame Shift Ins (INS) | VAF 49/169 reads (29%) | called by mutect2, pindel, varscan2
- ERI1 | c.157T>C p.F53L | Missense Mutation (SNP) | VAF 63/224 reads (28%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESRRB | c.1222C>T p.Q408* | Nonsense Mutation (SNP) | VAF 46/552 reads (8%) | called by muse, mutect2
- EYS | c.3697G>T p.G1233W | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM171B | c.2081del p.K694Rfs*18 | Frame Shift Del (DEL) | VAF 92/337 reads (27%) | called by mutect2, pindel, varscan2
- FARP1 | c.46del p.A16Pfs*83 | Frame Shift Del (DEL) | VAF 56/259 reads (22%) | called by mutect2, pindel, varscan2
- FARP1 | c.1692G>A p.S564= | Splice Region (SNP) | VAF 30/102 reads (29%) | called by muse, mutect2, varscan2
- FCSK | c.1067_1068+1del | In Frame Del (DEL) | VAF 43/144 reads (30%) | called by mutect2, pindel, varscan2
- FGF19 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- FGFR2 | c.2288_2289del p.L763Hfs*4 | Frame Shift Del (DEL) | VAF 234/530 reads (44%) | called by pindel, varscan2
- FIZ1 | c.921del p.L308Cfs*182 | Frame Shift Del (DEL) | VAF 13/142 reads (9%) | called by mutect2, pindel
- FLNA | c.7087dup p.A2363Gfs*22 (on ENST00000369850 / NM_001110556.2; = p.A2355Gfs*22 on NM_001456.3) | Frame Shift Ins (INS) | VAF 105/469 reads (22%) | called by mutect2, pindel, varscan2
- FTHL17 | c.266dup p.E90Rfs*79 | Frame Shift Ins (INS) | VAF 49/235 reads (21%) | called by mutect2, pindel, varscan2
- GALNT18 | c.1162A>G p.K388E | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- GAS2L1 | c.1653del p.D552Tfs*64 | Frame Shift Del (DEL) | VAF 18/216 reads (8%) | called by mutect2, pindel
- GBA3 | c.608G>T p.R203I | Missense Mutation (SNP) | VAF 67/252 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GOLGA8B | c.193C>T p.H65Y | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.453); called by mutect2, varscan2
- GREB1L | c.1166del p.N389Tfs*3 | Frame Shift Del (DEL) | VAF 54/197 reads (27%) | called by mutect2, pindel, varscan2
- GRHPR | c.423G>A p.W141* | Nonsense Mutation (SNP) | VAF 122/504 reads (24%) | called by muse, varscan2
- GSK3A | c.798-2A>G p.X266_splice | Splice Site (SNP) | VAF 48/182 reads (26%) | called by muse, mutect2, varscan2
- GSTT2 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 36/732 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.038); called by muse, mutect2
- H2BC4 | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 96/510 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HCLS1 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.439); called by muse, mutect2
- HDAC5 | c.546G>T p.E182D | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- HEPACAM2 | c.80-1G>A p.X27_splice (on ENST00000394468 / NM_001039372.4; = p.G15S on NM_198151.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 37/163 reads (23%) | called by muse, mutect2
- HLA-DMA | c.572A>T p.N191I | Missense Mutation (SNP) | VAF 98/416 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- HNRNPDL | c.867del p.K289Nfs*3 | Frame Shift Del (DEL) | VAF 22/73 reads (30%) | called by mutect2, pindel, varscan2
- HOATZ | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 100/362 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IFT172 | c.4494G>T p.E1498D | Missense Mutation (SNP) | VAF 78/353 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IKZF2 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 65/211 reads (31%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- IMPG2 | c.3704_3705del p.E1235Afs*46 | Frame Shift Del (DEL) | VAF 52/256 reads (20%) | called by pindel, varscan2
- INSYN2A | c.1141G>T p.G381W | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITIH1 | c.813+2T>C p.X271_splice | Splice Site (SNP) | VAF 35/135 reads (26%) | called by muse, mutect2, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 126/233 reads (54%) | called by mutect2, varscan2
- JARID2 | c.245del p.K82Rfs*49 | Frame Shift Del (DEL) | VAF 58/252 reads (23%) | called by mutect2, pindel, varscan2
- KANSL1L | c.2810dup p.D938Gfs*4 | Frame Shift Ins (INS) | VAF 94/387 reads (24%) | called by mutect2, varscan2
- KAT8 | c.966del p.Y323Tfs*48 | Frame Shift Del (DEL) | VAF 90/380 reads (24%) | called by mutect2, pindel, varscan2
- KCNC2 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); called by muse, mutect2
- KDM1A | c.2435A>G p.H812R | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM2B | c.3141del p.I1048Sfs*60 | Frame Shift Del (DEL) | VAF 14/166 reads (8%) | called by mutect2, pindel
- KEAP1 | c.1424T>C p.V475A | Missense Mutation (SNP) | VAF 88/361 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIAA1755 | c.1601T>C p.L534P | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- KIF3B | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIF7 | c.1709del p.G570Vfs*29 | Frame Shift Del (DEL) | VAF 135/519 reads (26%) | called by mutect2, pindel, varscan2
- KMT2A | c.1660del p.Q554Sfs*13 | Frame Shift Del (DEL) | VAF 42/327 reads (13%) | called by mutect2, pindel, varscan2
- KMT2B | c.7588C>T p.Q2530* | Nonsense Mutation (SNP) | VAF 29/138 reads (21%) | called by muse, mutect2, varscan2
- KRT82 | c.196del p.R66Gfs*2 | Frame Shift Del (DEL) | VAF 54/212 reads (25%) | called by mutect2, pindel, varscan2
- KRTAP26-1 | c.394T>A p.Y132N | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.086); called by muse, mutect2
- KRTCAP3 | c.167C>G p.P56R | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- LCE1E | c.173del p.G58Afs*20 | Frame Shift Del (DEL) | VAF 122/423 reads (29%) | called by mutect2, pindel, varscan2
- LCP2 | c.679del p.T227Rfs*9 | Frame Shift Del (DEL) | VAF 75/265 reads (28%) | called by mutect2, pindel, varscan2
- LGALS9 | c.542C>A p.P181H (on ENST00000395473 / NM_009587.3; = p.P149H on NM_002308.4) | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.466); called by muse, mutect2
- LMF2 | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 79/293 reads (27%) | called by muse, mutect2, varscan2
- LRP2 | c.4520G>A p.S1507N | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- LRRC37A | c.3599C>T p.A1200V | Missense Mutation (SNP) | VAF 267/571 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- LRRC58 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- LRRC8A | c.160T>C p.C54R | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAP10 | c.1456A>G p.N486D | Missense Mutation (SNP) | VAF 36/358 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MAP7D1 | c.107del p.P36Hfs*20 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, varscan2
- MBD6 | c.429del p.S144Lfs*35 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- MCF2L | c.1918C>A p.L640M (on ENST00000375608; = p.L608M on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- MCPH1 | c.1402del p.T468Pfs*32 | Frame Shift Del (DEL) | VAF 119/420 reads (28%) | called by mutect2, pindel, varscan2
- METAP1 | c.676A>G p.N226D | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- MFAP3L | c.981del p.E328Sfs*16 | Frame Shift Del (DEL) | VAF 33/433 reads (8%) | called by mutect2, pindel
- MFSD4A | c.353C>G p.A118G | Missense Mutation (SNP) | VAF 176/305 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGAT4D | c.926del p.L309* | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | called by mutect2, varscan2
- MIOS | c.1677G>A p.M559I | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- MLF1 | c.172A>G p.N58D | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP23B | c.40dup p.A14Gfs*352 | Frame Shift Ins (INS) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- MPI | c.706_708del p.E236del | In Frame Del (DEL) | VAF 88/375 reads (23%) | called by mutect2, pindel, varscan2
- MPP5 | c.1364del p.N455Mfs*10 | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | called by mutect2, pindel, varscan2
- MRC1 | c.1987T>A p.Y663N | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- MRPS27 | c.1233G>T p.K411N | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- MUC16 | c.712C>A p.L238I | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.135); called by muse, mutect2
- MYO15A | c.2297G>A p.R766Q | Missense Mutation (SNP) | VAF 85/294 reads (29%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO15B | c.3750G>C p.Q1250H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- MYO16 | c.5413A>G p.R1805G | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MYO1A | c.758T>C p.V253A | Missense Mutation (SNP) | VAF 209/762 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- MYO1B | c.2998A>G p.N1000D (on ENST00000304164; = p.N942D on NM_012223.5) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.253); called by muse, mutect2
- NAGS | c.701+2T>C p.X234_splice | Splice Site (SNP) | VAF 92/372 reads (25%) | called by muse, mutect2, varscan2
- NFKB2 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP13 | c.794T>C p.V265A | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- NOTCH1 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NPAT | c.1642del p.S548Vfs*11 | Frame Shift Del (DEL) | VAF 33/107 reads (31%) | called by mutect2, pindel, varscan2
- NPC1L1 | c.2921C>A p.P974H | Missense Mutation (SNP) | VAF 44/419 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- NRXN1 | c.1851del p.L618Cfs*51 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by pindel, varscan2
- NTN1 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 80/324 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NTRK1 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 17/245 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2
- OAS2 | c.1974del p.E659Kfs*53 (on ENST00000342315 / NM_016817.3; = p.E659Kfs*26 on NM_002535.3) | Frame Shift Del (DEL) | VAF 58/257 reads (23%) | called by mutect2, pindel, varscan2
- OBSL1 | c.3692G>A p.C1231Y | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.216); called by muse, mutect2
- OR4K1 | c.352A>G p.M118V | Missense Mutation (SNP) | VAF 53/438 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- OR4K13 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.125); called by muse, mutect2
- OXSR1 | c.777dup p.Y260Ifs*6 | Frame Shift Ins (INS) | VAF 29/98 reads (30%) | called by mutect2, pindel, varscan2
- P2RX4 | c.928A>G p.T310A | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); called by muse, mutect2
- PC | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 82/382 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PCDH9 | c.3350T>A p.L1117* (on ENST00000377865 / NM_203487.3; = p.L1083* on NM_020403.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/82 reads (12%) | called by muse, varscan2
- PCDHA10 | c.74T>C p.V25A | Missense Mutation (SNP) | VAF 72/298 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDE4DIP | c.2471T>C p.I824T | Missense Mutation (SNP) | VAF 21/217 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- PDE6B | c.1364A>G p.H455R | Missense Mutation (SNP) | VAF 90/316 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- PDS5B | c.2170del p.R724Vfs*32 | Frame Shift Del (DEL) | VAF 15/170 reads (9%) | called by mutect2, pindel
- PER2 | c.2696C>A p.P899H | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PGM2L1 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PHLDB2 | c.2788G>T p.G930* (on ENST00000393925 / NM_001134439.2; = p.G887* on NM_145753.2) | Nonsense Mutation (SNP) | VAF 47/191 reads (25%) | called by muse, mutect2, varscan2
- PI16 | c.1312A>T p.N438Y | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- PIK3R1 | c.1732_1733del p.D578Pfs*23 (on ENST00000521381 / NM_181523.3; = p.D308Pfs*23 on NM_181504.4) | Frame Shift Del (DEL) | VAF 22/106 reads (21%) | called by pindel, varscan2
- PIK3R1 | c.1761del p.G588Vfs*7 (on ENST00000521381 / NM_181523.3; = p.G318Vfs*7 on NM_181504.4) | Frame Shift Del (DEL) | VAF 70/214 reads (33%) | called by mutect2, pindel, varscan2
- PKD1 | c.10597G>A p.A3533T (on ENST00000262304 / NM_001009944.3; = p.A3532T on NM_000296.4) | Missense Mutation (SNP) | VAF 87/314 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PKD1 | c.1919G>T p.C640F | Missense Mutation (SNP) | VAF 79/411 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLA2G2A | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2
- PLB1 | c.2125C>T p.Q709* | Nonsense Mutation (SNP) | VAF 50/291 reads (17%) | called by muse, mutect2, varscan2
- PLCE1 | c.6890C>T p.T2297I | Missense Mutation (SNP) | VAF 73/322 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PLEKHH3 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2
- PLXND1 | c.5201del p.P1734Hfs*40 | Frame Shift Del (DEL) | VAF 12/134 reads (9%) | called by mutect2, pindel
- PNISR | c.2399C>G p.S800C | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PNISR | c.1113dup p.Q372Tfs*26 | Frame Shift Ins (INS) | VAF 48/188 reads (26%) | called by mutect2, pindel, varscan2
- PNMA3 | c.419A>T p.E140V | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 72/253 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- PODNL1 | c.152_153del p.V51Gfs*3 | Frame Shift Del (DEL) | VAF 40/223 reads (18%) | called by pindel, varscan2
- POF1B | c.1396A>G p.N466D | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- POMT1 | c.1748T>G p.L583R | Missense Mutation (SNP) | VAF 180/624 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- POP4 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.036); called by muse, mutect2
- PPEF1 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRDM5 | c.94-2A>G p.X32_splice | Splice Site (SNP) | VAF 58/184 reads (32%) | called by muse, mutect2, varscan2
- PRKD1 | c.884del p.F295Sfs*30 | Frame Shift Del (DEL) | VAF 76/270 reads (28%) | called by mutect2, pindel, varscan2
- PRPF4 | c.1285A>T p.T429S (on ENST00000374198 / NM_001322267.2; = p.T430S on NM_004697.5) | Missense Mutation (SNP) | VAF 80/278 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PRSS36 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.691); called by muse, mutect2
- PSEN2 | c.142-2A>G p.X48_splice | Splice Site (SNP) | VAF 25/418 reads (6%) | called by muse, mutect2
- QARS1 | c.977-2A>G p.X326_splice | Splice Site (SNP) | VAF 121/353 reads (34%) | called by muse, mutect2, varscan2
- RAB36 | c.472del p.V158Wfs*41 | Frame Shift Del (DEL) | VAF 19/235 reads (8%) | called by mutect2, pindel
- RABL6 | c.2168del p.G723Vfs*47 | Frame Shift Del (DEL) | VAF 39/113 reads (35%) | called by mutect2, pindel, varscan2
- RALGAPB | c.1142del p.P381Hfs*11 | Frame Shift Del (DEL) | VAF 26/248 reads (10%) | called by mutect2, pindel
- RASA3 | c.1354A>G p.M452V | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- RESF1 | c.1341_1342del p.Q447Hfs*33 | Frame Shift Del (DEL) | VAF 28/144 reads (19%) | called by mutect2, pindel, varscan2
- REV1 | c.1139A>T p.N380I | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.203); called by muse, varscan2
- REV1 | c.86T>C p.L29S | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- RHOBTB1 | c.890del p.L297* | Frame Shift Del (DEL) | VAF 104/344 reads (30%) | called by mutect2, pindel, varscan2
- RLIM | c.1556C>T p.T519I | Missense Mutation (SNP) | VAF 60/220 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- RNF168 | c.1652A>G p.H551R | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RNF213 | c.7708G>C p.A2570P | Missense Mutation (SNP) | VAF 110/352 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- RNF220 | c.1148G>C p.S383T | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0.011); called by muse, mutect2
- RP1L1 | c.4495del p.A1499Lfs*25 | Frame Shift Del (DEL) | VAF 24/92 reads (26%) | called by mutect2, pindel, varscan2
- RPL11 | c.33G>A p.M11I (on ENST00000374550 / NM_001199802.1; = p.M12I on NM_000975.5) | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); called by muse, mutect2
- RPL22 | c.267del p.K89Nfs*3 | Frame Shift Del (DEL) | VAF 51/211 reads (24%) | called by mutect2, pindel, varscan2
- SBNO2 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 89/280 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN8A | c.4281+2T>C p.X1427_splice | Splice Site (SNP) | VAF 9/125 reads (7%) | called by muse, mutect2
- SEC31B | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2
- SERPINF2 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 67/265 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SF3A1 | c.959G>T p.S320I | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SHANK3 | c.5080G>A p.A1694T | Missense Mutation (SNP) | VAF 221/825 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SHC3 | c.1607T>C p.M536T | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SIN3A | c.107C>A p.P36H | Missense Mutation (SNP) | VAF 106/363 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- SLC16A10 | c.980del p.N327Ifs*30 | Frame Shift Del (DEL) | VAF 103/315 reads (33%) | called by mutect2, pindel, varscan2
- SLC2A6 | c.810del p.H271Tfs*11 | Frame Shift Del (DEL) | VAF 17/99 reads (17%) | called by mutect2, pindel, varscan2
- SLC4A11 | c.252del p.F84Lfs*32 | Frame Shift Del (DEL) | VAF 258/682 reads (38%) | called by mutect2, varscan2
- SLC5A3 | c.2093T>C p.L698P | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC5A5 | c.1397A>G p.Y466C | Missense Mutation (SNP) | VAF 109/285 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SMARCAD1 | c.2606A>G p.K869R | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- SMC3 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- SNRPA | c.668T>C p.M223T | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SNRPA | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SOWAHC | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 105/441 reads (24%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA2L | c.761dup p.A255Gfs*29 | Frame Shift Ins (INS) | VAF 64/211 reads (30%) | called by mutect2, pindel, varscan2
- SPATA6 | c.87G>T p.E29D | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- SPATC1 | c.1030dup p.Q344Pfs*27 | Frame Shift Ins (INS) | VAF 18/75 reads (24%) | called by mutect2, pindel, varscan2
- SPOPL | c.19C>A p.P7T | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- SPTAN1 | c.6328G>A p.A2110T | Missense Mutation (SNP) | VAF 26/574 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); called by muse, mutect2
- SSH2 | c.143C>G p.A48G | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- STIP1 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 29/372 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); called by muse, mutect2
- STXBP1 | c.151A>G p.M51V | Missense Mutation (SNP) | VAF 91/322 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SUCNR1 | c.232A>G p.M78V | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SUPV3L1 | c.485del p.F162Sfs*2 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | called by mutect2, pindel
- TAPT1 | c.697del p.R233Efs*6 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | called by mutect2, pindel, varscan2
- TBC1D13 | c.1135C>T p.Q379* | Nonsense Mutation (SNP) | VAF 14/242 reads (6%) | called by muse, mutect2
- TBX22 | c.116del p.K39Rfs*74 | Frame Shift Del (DEL) | VAF 53/671 reads (8%) | called by mutect2, pindel
- TCF19 | c.473C>G p.A158G | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.135); called by muse, mutect2
- TEX44 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 53/564 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.191); called by muse, mutect2
- THAP3 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 18/313 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.042); called by muse, mutect2
- TMC3 | c.2963A>G p.Q988R | Missense Mutation (SNP) | VAF 70/254 reads (28%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMPRSS11B | c.1196T>C p.V399A | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- TNNC2 | c.198C>T p.D66= | Splice Region (SNP) | VAF 16/198 reads (8%) | called by muse, mutect2
- TNRC18 | c.2345del p.G782Afs*91 | Frame Shift Del (DEL) | VAF 24/226 reads (11%) | called by mutect2, varscan2
- TOX4 | c.943T>G p.S315A | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- TP53BP2 | c.594del p.V199* (on ENST00000343537 / NM_001031685.3; = p.V70* on NM_005426.2) | Frame Shift Del (DEL) | VAF 81/156 reads (52%) | called by mutect2, pindel, varscan2
- TP53I13 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAF2 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- TRANK1 | c.3967A>T p.R1323* | Nonsense Mutation (SNP) | VAF 23/359 reads (6%) | called by muse, mutect2
- TRIM32 | c.899C>G p.T300R | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.083); called by muse, mutect2
- UBR2 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 66/237 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT1A10 | c.156dup p.H53Afs*2 | Frame Shift Ins (INS) | VAF 66/202 reads (33%) | called by mutect2, varscan2
- UNC5A | c.1901del p.G634Dfs*3 | Frame Shift Del (DEL) | VAF 26/111 reads (23%) | called by mutect2, pindel, varscan2
- USP43 | c.953G>A p.G318D | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.021); called by muse, mutect2
- USP47 | c.3360del p.G1121Efs*22 (on ENST00000399455 / NM_001372095.1; = p.G1033Efs*22 on NM_017944.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | called by mutect2, pindel, varscan2
- USP5 | c.2158G>A p.A720T (on ENST00000229268 / NM_001098536.2; = p.A697T on NM_003481.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.078); called by muse, mutect2
- USP9X | c.82del p.L28Sfs*51 | Frame Shift Del (DEL) | VAF 51/250 reads (20%) | called by mutect2, pindel, varscan2
- UTRN | c.6074T>C p.I2025T | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- UVRAG | c.452dup p.N151Kfs*2 | Frame Shift Ins (INS) | VAF 17/79 reads (22%) | called by mutect2, pindel, varscan2
- VAC14 | c.1999A>G p.K667E | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- VCAN | c.4519C>A p.H1507N | Missense Mutation (SNP) | VAF 91/312 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- VEZF1 | c.88dup p.L30Pfs*10 | Frame Shift Ins (INS) | VAF 62/208 reads (30%) | called by mutect2, pindel, varscan2
- VOPP1 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- WAC | c.61del p.D21Tfs*171 | Frame Shift Del (DEL) | VAF 14/122 reads (11%) | called by mutect2, pindel
- WDR13 | c.42-1G>T p.X14_splice | Splice Site (SNP) | VAF 4/53 reads (8%) | called by muse, mutect2
- WDR97 | c.412G>A p.G138S | Missense Mutation (SNP) | VAF 92/306 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WWP1 | c.1504T>C p.W502R | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- XIRP2 | c.7054_7055del p.S2352Ffs*14 (on ENST00000628543; = p.S2527Ffs*14 on NM_152381.6) | Frame Shift Del (DEL) | VAF 40/156 reads (26%) | called by pindel, varscan2
- YBX2 | c.677del p.P226Hfs*22 | Frame Shift Del (DEL) | VAF 37/132 reads (28%) | called by mutect2, pindel, varscan2
- ZC3H6 | c.295del p.R99Efs*23 | Frame Shift Del (DEL) | VAF 22/84 reads (26%) | called by mutect2, pindel, varscan2
- ZCCHC18 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 22/263 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2
- ZDBF2 | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ZFP36L1 | c.963G>T p.L321F | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF112 | c.1664G>A p.C555Y (on ENST00000337401 / NM_001083335.2; = p.C549Y on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF236 | c.661+2T>C p.X221_splice | Splice Site (SNP) | VAF 14/186 reads (8%) | called by muse, mutect2
- ZNF236 | c.1698dup p.A567Cfs*6 | Frame Shift Ins (INS) | VAF 22/166 reads (13%) | called by mutect2, pindel
- ZNF43 | c.834A>G p.I278M | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ZNF506 | c.640T>C p.S214P | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ZNF614 | c.328C>T p.L110F | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF768 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 39/229 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ZNF772 | c.5_6insAGC p.A4dup | In Frame Ins (INS) | VAF 39/123 reads (32%) | called by mutect2, pindel, varscan2
- ZZEF1 | c.3751A>G p.K1251E | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- ABCC6 | c.354A>G p.A118= | Silent (SNP) | VAF 23/303 reads (8%) | called by muse, mutect2, varscan2
- ABCD1 | c.1260C>T p.H420= | Silent (SNP) | VAF 61/560 reads (11%) | catalogued as rs782066367, COSV54387999; called by muse, mutect2, varscan2
- AC231657.3 | c.759G>A p.S253= | Silent (SNP) | VAF 42/170 reads (25%) | called by muse, mutect2, varscan2
- ACSBG2 | c.210C>T p.L70= | Silent (SNP) | VAF 63/625 reads (10%) | catalogued as rs577031271; called by muse, mutect2, varscan2
- ADAM9 | c.2352G>A p.Q784= | Silent (SNP) | VAF 53/256 reads (21%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.3399C>T p.R1133= | Silent (SNP) | VAF 73/306 reads (24%) | catalogued as COSV61275757; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4266G>A p.P1422= | Silent (SNP) | VAF 34/135 reads (25%) | catalogued as rs751834654; called by muse, mutect2, varscan2
- ADGRA3 | c.2841G>A p.E947= | Silent (SNP) | VAF 28/506 reads (6%) | catalogued as COSV99293164; called by muse, mutect2
- AGAP5 | c.381C>T p.S127= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs1554962767; called by mutect2, varscan2
- AGRN | c.6049T>C p.L2017= | Silent (SNP) | VAF 51/400 reads (13%) | called by muse, mutect2
- ANKRD11 | c.7221G>A p.T2407= | Silent (SNP) | VAF 140/658 reads (21%) | catalogued as rs761715813; called by muse, mutect2, varscan2
- ANKRD2 | c.751C>T p.L251= | Silent (SNP) | VAF 46/152 reads (30%) | called by muse, mutect2, varscan2
- APBA2 | c.600G>A p.E200= | Silent (SNP) | VAF 41/706 reads (6%) | called by muse, mutect2
- ARHGAP12 | c.840T>C p.R280= | Silent (SNP) | VAF 63/245 reads (26%) | called by muse, mutect2, varscan2
- ARHGAP45 | c.358C>T p.L120= | Silent (SNP) | VAF 14/396 reads (4%) | called by muse, mutect2
- ARHGEF26 | c.2361C>T p.D787= | Silent (SNP) | VAF 12/212 reads (6%) | called by muse, mutect2
- ATG4D | c.750G>A p.S250= | Silent (SNP) | VAF 44/159 reads (28%) | catalogued as rs757470389, COSV58763188; called by muse, mutect2, varscan2
- AURKB | c.675G>A p.A225= | Silent (SNP) | VAF 44/117 reads (38%) | catalogued as rs762861088; called by muse, mutect2, varscan2
- BCORL1 | c.2325T>C p.A775= | Silent (SNP) | VAF 26/178 reads (15%) | called by muse, mutect2, varscan2
- BHLHA15 | c.255G>A p.R85= | Silent (SNP) | VAF 20/432 reads (5%) | called by muse, mutect2
- BMPER | c.2004C>T p.N668= | Silent (SNP) | VAF 100/394 reads (25%) | called by muse, mutect2, varscan2
- C1QTNF12 | c.627C>T p.A209= | Silent (SNP) | VAF 34/143 reads (24%) | called by muse, mutect2, varscan2
- CACNA1G | c.5050C>T p.L1684= | Silent (SNP) | VAF 32/125 reads (26%) | called by muse, mutect2, varscan2
- CACTIN | c.2097C>T p.C699= | Silent (SNP) | VAF 83/257 reads (32%) | catalogued as rs1384761069; called by muse, mutect2, varscan2
- CARD14 | c.198C>T p.S66= | Silent (SNP) | VAF 24/207 reads (12%) | catalogued as rs1254076623, COSV60121561; called by muse, mutect2, varscan2
- CCDC80 | c.1563G>A p.E521= | Silent (SNP) | VAF 34/253 reads (13%) | called by muse, mutect2, varscan2
- CD244 | c.177A>G p.S59= | Silent (SNP) | VAF 20/504 reads (4%) | called by muse, mutect2
- CHST12 | c.1122C>T p.S374= | Silent (SNP) | VAF 20/184 reads (11%) | catalogued as rs908477504; called by muse, mutect2, varscan2
- CMYA5 | c.8616C>T p.H2872= | Silent (SNP) | VAF 44/153 reads (29%) | called by muse, mutect2, varscan2
- COX10 | c.1188C>T p.G396= | Silent (SNP) | VAF 90/328 reads (27%) | catalogued as rs1472420802; called by muse, mutect2, varscan2
- CTNNB1 | c.1506C>T p.S502= | Silent (SNP) | VAF 21/77 reads (27%) | called by muse, mutect2, varscan2
- CXCR3 | c.39C>T p.D13= | Silent (SNP) | VAF 70/261 reads (27%) | catalogued as rs746084711; called by muse, mutect2, varscan2
- CXXC1 | c.1278C>T p.G426= | Silent (SNP) | VAF 17/351 reads (5%) | called by muse, mutect2
- DAB2IP | c.3099C>T p.D1033= (on ENST00000408936; = p.D1005= on NM_032552.3) | Silent (SNP) | VAF 60/180 reads (33%) | catalogued as rs539727039, COSV52261633; called by muse, mutect2, varscan2
- DACT3 | c.1221C>A p.A407= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs1269403523; called by muse, mutect2, varscan2
- DNAH12 | c.3354T>C p.S1118= (on ENST00000351747; = p.S1141= on NM_001366028.2) | Silent (SNP) | VAF 89/334 reads (27%) | called by muse, mutect2, varscan2
- DNAI2 | c.1407C>T p.C469= | Silent (SNP) | VAF 136/559 reads (24%) | catalogued as rs143723454, COSV100210152; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNER | c.1074C>T p.C358= | Silent (SNP) | VAF 16/280 reads (6%) | catalogued as rs1197066778; called by muse, mutect2
- DSP | c.2142T>C p.N714= | Silent (SNP) | VAF 19/207 reads (9%) | called by muse, mutect2
- DYNC2H1 | c.921G>A p.Q307= | Silent (SNP) | VAF 9/194 reads (5%) | called by muse, mutect2
- DYSF | c.3762G>A p.R1254= | Silent (SNP) | VAF 26/522 reads (5%) | catalogued as COSV50540062; called by muse, mutect2
- EIF2AK4 | c.4290C>T p.Y1430= | Silent (SNP) | VAF 46/127 reads (36%) | catalogued as rs374541428; called by muse, mutect2, varscan2
- ELOB | c.348C>T p.A116= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as rs769106392; called by muse, mutect2, varscan2
- ENGASE | c.456C>T p.F152= | Silent (SNP) | VAF 16/192 reads (8%) | catalogued as COSV56137717; called by muse, mutect2
- EPHA8 | c.1095G>A p.V365= | Silent (SNP) | VAF 68/286 reads (24%) | catalogued as rs148326577; called by muse, mutect2, varscan2
- EPHB3 | c.2076C>T p.P692= | Silent (SNP) | VAF 18/335 reads (5%) | called by muse, mutect2
- EPHB4 | c.2772C>T p.Y924= | Silent (SNP) | VAF 81/336 reads (24%) | catalogued as rs764404042, COSV62268892; called by muse, mutect2, varscan2
- EPPK1 | c.6579G>A p.T2193= | Silent (SNP) | VAF 88/401 reads (22%) | catalogued as rs377540656; called by muse, mutect2, varscan2
- EXPH5 | c.3702G>A p.T1234= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs746335515, COSV99760794; called by muse, mutect2, varscan2
- FANCG | c.303G>A p.E101= | Silent (SNP) | VAF 17/516 reads (3%) | catalogued as rs1185376630; called by muse, mutect2
- FBN2 | c.4650G>A p.T1550= | Silent (SNP) | VAF 129/502 reads (26%) | catalogued as rs773637235; called by muse, mutect2, varscan2
- FRMD8 | c.691C>T p.L231= | Silent (SNP) | VAF 19/85 reads (22%) | called by muse, mutect2, varscan2
- FSD1 | c.1161G>C p.T387= | Silent (SNP) | VAF 170/582 reads (29%) | catalogued as rs1475967545; called by muse, mutect2, varscan2
- FZD6 | c.1059T>C p.I353= | Silent (SNP) | VAF 14/225 reads (6%) | called by muse, mutect2
- GABBR1 | c.516C>T p.I172= | Silent (SNP) | VAF 88/391 reads (23%) | called by muse, mutect2, varscan2
- GABBR2 | c.165G>A p.P55= | Silent (SNP) | VAF 30/150 reads (20%) | called by muse, mutect2, varscan2
- GID8 | c.561G>A p.E187= | Silent (SNP) | VAF 9/201 reads (4%) | catalogued as rs1297745486; called by muse, mutect2
- GIGYF1 | c.1720C>T p.L574= | Silent (SNP) | VAF 18/175 reads (10%) | called by muse, mutect2, varscan2
- GLIS2 | c.264G>A p.G88= | Silent (SNP) | VAF 28/355 reads (8%) | called by muse, mutect2
- GMPPB | c.684C>T p.G228= | Silent (SNP) | VAF 13/164 reads (8%) | called by muse, mutect2
- GNL3L | c.123C>A p.P41= | Silent (SNP) | VAF 59/239 reads (25%) | catalogued as COSV100328341; called by muse, varscan2
- GPR135 | c.768G>A p.A256= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as rs1309317959; called by muse, mutect2, varscan2
- GPR18 | c.360C>T p.Y120= | Silent (SNP) | VAF 21/348 reads (6%) | called by muse, mutect2
- GUCY2D | c.546G>A p.A182= | Silent (SNP) | VAF 63/194 reads (32%) | called by muse, mutect2, varscan2
- HDLBP | c.1362C>T p.S454= | Silent (SNP) | VAF 30/130 reads (23%) | catalogued as rs138859216; called by muse, mutect2, varscan2
- HNF4G | c.1185A>G p.S395= (on ENST00000354370 / NM_001330561.2; = p.S442= on NM_004133.5) | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as rs1290436217; called by muse, mutect2, varscan2
- HSPA14 | c.765G>A p.A255= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs559179634; called by muse, mutect2, varscan2
- HSPA4L | c.1620T>C p.C540= | Silent (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- IARS1 | c.1956A>G p.V652= | Silent (SNP) | VAF 41/144 reads (28%) | called by muse, mutect2, varscan2
- ICAM2 | c.703C>T p.L235= | Silent (SNP) | VAF 14/184 reads (8%) | catalogued as COSV99856911; called by muse, mutect2
- IFI27L2 | c.159T>A p.G53= | Silent (SNP) | VAF 27/284 reads (10%) | called by muse, mutect2
- IK | c.351C>T p.T117= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as rs750421122; called by muse, mutect2
- IL27RA | c.1554G>A p.L518= | Silent (SNP) | VAF 14/99 reads (14%) | called by muse, mutect2, varscan2
- IL5 | c.220C>T p.L74= | Silent (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2, varscan2
- INF2 | c.549C>T p.N183= | Silent (SNP) | VAF 263/866 reads (30%) | catalogued as rs1555373624; ClinVar: likely benign; called by muse, mutect2, varscan2
- INPP4A | c.1995C>A p.A665= (on ENST00000074304 / NM_001134224.1; = p.A626= on NM_001566.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 96/384 reads (25%) | called by muse, mutect2, varscan2
- ITPR3 | c.3867G>A p.L1289= | Silent (SNP) | VAF 130/434 reads (30%) | called by muse, mutect2, varscan2
- ITPRID1 | c.1716C>T p.H572= | Silent (SNP) | VAF 62/198 reads (31%) | catalogued as rs546082086; called by muse, mutect2, varscan2
- KATNAL1 | c.658C>T p.L220= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs775929118; called by muse, mutect2, varscan2
- KCNN2 | c.285C>T p.G95= (on ENST00000264773; = p.G307= on NM_021614.4) | Silent (SNP) | VAF 79/307 reads (26%) | called by muse, varscan2
- KIAA0319L | c.2751G>A p.V917= | Silent (SNP) | VAF 61/258 reads (24%) | catalogued as rs766878879; called by muse, mutect2, varscan2
- KIFC1 | c.1062C>T p.D354= | Silent (SNP) | VAF 30/250 reads (12%) | catalogued as rs567076351; called by muse, mutect2, varscan2
- KIZ | c.72G>A p.Q24= | Silent (SNP) | VAF 30/104 reads (29%) | called by muse, mutect2, varscan2
- KRT4 | c.1218T>C p.A406= | Silent (SNP) | VAF 43/440 reads (10%) | called by muse, mutect2
- LARGE2 | c.894C>T p.N298= | Silent (SNP) | VAF 16/222 reads (7%) | catalogued as rs747156575, COSV57661794; called by muse, mutect2
- LMTK2 | c.738G>A p.A246= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as rs370355112; called by muse, mutect2, varscan2
- LPCAT1 | c.366G>A p.A122= | Silent (SNP) | VAF 82/420 reads (20%) | catalogued as rs896406619, COSV99358790; called by muse, mutect2, varscan2
- LRRC10 | c.51C>T p.C17= | Silent (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2
- MAGI1 | c.2865C>T p.G955= (on ENST00000402939 / NM_001033057.2; = p.G983= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/390 reads (7%) | catalogued as rs747001044; called by muse, mutect2
- MAP10 | c.321G>A p.S107= | Silent (SNP) | VAF 30/406 reads (7%) | called by muse, mutect2
- MAPK8IP2 | c.1026C>T p.S342= | Silent (SNP) | VAF 114/409 reads (28%) | catalogued as rs972044560; called by muse, mutect2, varscan2
- MAVS | c.300G>A p.S100= | Silent (SNP) | VAF 44/91 reads (48%) | catalogued as rs781011254; called by muse, mutect2, varscan2
- MMP24 | c.1236G>A p.E412= | Silent (SNP) | VAF 160/408 reads (39%) | called by muse, varscan2
- MSS51 | c.105C>T p.P35= | Silent (SNP) | VAF 22/253 reads (9%) | called by muse, mutect2
- MXRA8 | c.696C>T p.R232= | Silent (SNP) | VAF 65/244 reads (27%) | catalogued as rs1331103131; called by muse, mutect2, varscan2
- MYH9 | c.2403G>A p.K801= | Silent (SNP) | VAF 138/517 reads (27%) | catalogued as rs777484384; called by muse, mutect2, varscan2
- MYO5C | c.603C>T p.T201= | Silent (SNP) | VAF 41/181 reads (23%) | catalogued as rs201556746; called by muse, mutect2, varscan2
- MYO7B | c.4275G>A p.T1425= | Silent (SNP) | VAF 61/260 reads (23%) | catalogued as rs775391994; called by muse, mutect2, varscan2
- NBAS | c.4725G>A p.A1575= | Silent (SNP) | VAF 34/345 reads (10%) | catalogued as rs368763420, COSV55734540; called by muse, mutect2
- NCKAP5 | c.1620C>T p.C540= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs765781290, COSV58461835; called by muse, mutect2, varscan2
- NCOA5 | c.840C>T p.N280= | Silent (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- NEK8 | c.1680G>A p.Q560= | Silent (SNP) | VAF 34/600 reads (6%) | called by muse, mutect2
- NEUROG2 | c.144A>G p.S48= | Silent (SNP) | VAF 32/121 reads (26%) | called by muse, mutect2, varscan2
- NOC3L | c.828G>C p.R276= | Silent (SNP) | VAF 29/159 reads (18%) | called by muse, mutect2, varscan2
- NOTCH1 | c.4932G>A p.L1644= | Silent (SNP) | VAF 32/125 reads (26%) | catalogued as COSV53097035; called by muse, mutect2, varscan2
- NPAP1 | c.870A>C p.L290= | Silent (SNP) | VAF 36/212 reads (17%) | called by muse, mutect2, varscan2
- NRBP2 | c.534C>T p.S178= | Silent (SNP) | VAF 18/330 reads (5%) | catalogued as COSV59919270; called by muse, mutect2
- NSD3 | c.4122T>C p.A1374= | Silent (SNP) | VAF 18/260 reads (7%) | called by muse, mutect2
- NYNRIN | c.1020C>A p.A340= | Silent (SNP) | VAF 76/236 reads (32%) | called by muse, mutect2, varscan2
- OTUD7A | c.1935C>T p.A645= (on ENST00000307050 / NM_001382637.1; = p.A638= on NM_130901.3) | Silent (SNP) | VAF 11/184 reads (6%) | catalogued as rs375289192, COSV100192848; called by muse, mutect2
- P2RX6 | c.882C>T p.Y294= | Silent (SNP) | VAF 38/126 reads (30%) | catalogued as rs764241676; called by muse, mutect2, varscan2
- PACS1 | c.96G>A p.P32= | Silent (SNP) | VAF 79/257 reads (31%) | catalogued as rs1234962005; called by muse, varscan2
- PCDHA7 | c.1359G>A p.P453= | Silent (SNP) | VAF 27/685 reads (4%) | catalogued as rs782151257, COSV65344260; called by muse, mutect2
- PCDHB4 | c.1569G>A p.L523= | Silent (SNP) | VAF 38/1138 reads (3%) | called by muse, mutect2
- PCNX3 | c.3093C>T p.A1031= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as rs755263946; called by muse, mutect2, varscan2
- PFKL | c.1035G>A p.R345= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs145858542; called by muse, mutect2, varscan2
- PHF20 | c.2643G>A p.P881= | Silent (SNP) | VAF 18/226 reads (8%) | catalogued as rs756688174; called by muse, mutect2
- PI16 | c.1098C>T p.S366= | Silent (SNP) | VAF 15/266 reads (6%) | called by muse, mutect2
- PIK3R4 | c.1254T>C p.I418= | Silent (SNP) | VAF 18/270 reads (7%) | called by muse, mutect2
- PKIA | c.93A>G p.A31= | Silent (SNP) | VAF 20/98 reads (20%) | called by muse, mutect2, varscan2
- PKLR | c.588C>T p.N196= | Silent (SNP) | VAF 42/416 reads (10%) | called by muse, mutect2, varscan2
- PLIN3 | c.180C>T p.C60= | Silent (SNP) | VAF 30/544 reads (6%) | catalogued as rs947646583, COSV55734868; called by muse, mutect2
- POLG2 | c.6C>T p.R2= | Silent (SNP) | VAF 73/650 reads (11%) | called by muse, mutect2, varscan2
- PPFIA3 | c.2526C>T p.T842= | Silent (SNP) | VAF 35/180 reads (19%) | catalogued as rs973825178; called by muse, mutect2, varscan2
- PROKR2 | c.879T>G p.G293= | Silent (SNP) | VAF 50/956 reads (5%) | called by muse, mutect2
- PRPF8 | c.6459T>A p.T2153= | Silent (SNP) | VAF 73/596 reads (12%) | called by muse, mutect2, varscan2
- PTGDS | c.144C>T p.L48= | Silent (SNP) | VAF 50/153 reads (33%) | called by muse, mutect2, varscan2
- PTMA | c.138G>A p.E46= (on ENST00000341369 / NM_001099285.2; = p.E45= on NM_002823.5) | Silent (SNP) | VAF 9/205 reads (4%) | catalogued as rs1162753494; called by muse, mutect2
- PTPRE | c.375T>C p.R125= | Silent (SNP) | VAF 53/229 reads (23%) | called by muse, mutect2, varscan2
- PTPRU | c.2571C>A p.P857= | Silent (SNP) | VAF 25/181 reads (14%) | called by muse, mutect2, varscan2
- RAET1G | c.771C>A p.S257= | Silent (SNP) | VAF 15/296 reads (5%) | called by muse, mutect2
- RALGDS | c.192G>A p.T64= | Silent (SNP) | VAF 33/487 reads (7%) | catalogued as rs896893855; called by muse, mutect2
- RAPH1 | c.615T>C p.S205= | Silent (SNP) | VAF 17/204 reads (8%) | called by muse, mutect2
- RBM15B | c.1236C>T p.G412= | Silent (SNP) | VAF 25/244 reads (10%) | catalogued as rs200311972; called by muse, mutect2
- REEP4 | c.351C>T p.T117= | Silent (SNP) | VAF 53/185 reads (29%) | catalogued as rs747496483; called by muse, mutect2, varscan2
- RELN | c.10059C>T p.H3353= | Silent (SNP) | VAF 70/317 reads (22%) | catalogued as rs201349789; called by muse, mutect2, varscan2
- REPS1 | c.1473T>A p.L491= | Silent (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
- RGS18 | c.207G>A p.L69= | Silent (SNP) | VAF 13/214 reads (6%) | called by muse, mutect2
- RIOX1 | c.172C>T p.L58= | Silent (SNP) | VAF 12/133 reads (9%) | catalogued as COSV100408116; called by muse, mutect2
- RPP25 | c.261C>T p.R87= | Silent (SNP) | VAF 17/286 reads (6%) | called by muse, mutect2
- RPUSD2 | c.597C>T p.I199= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV100225281; called by muse, mutect2, varscan2
- RRBP1 | c.2754G>A p.L918= (on ENST00000377813 / NM_001365613.2; = p.L485= on NM_004587.3) | Silent (SNP) | VAF 26/75 reads (35%) | called by muse, mutect2, varscan2
- RTP1 | c.396C>T p.C132= | Silent (SNP) | VAF 14/177 reads (8%) | catalogued as rs754308163; called by muse, mutect2
- SCRT1 | c.816C>T p.G272= | Silent (SNP) | VAF 10/238 reads (4%) | called by muse, mutect2
- SDK1 | c.1107C>T p.S369= | Silent (SNP) | VAF 22/292 reads (8%) | catalogued as rs772013334, COSV67376447; called by muse, mutect2
- SEC24B | c.1425A>G p.A475= | Silent (SNP) | VAF 91/372 reads (24%) | called by muse, mutect2, varscan2
- SEMA7A | c.1131C>A p.T377= | Silent (SNP) | VAF 19/372 reads (5%) | called by muse, mutect2
- SH3PXD2A | c.219C>T p.P73= | Silent (SNP) | VAF 21/216 reads (10%) | called by muse, mutect2
- SHANK1 | c.2661G>A p.R887= | Silent (SNP) | VAF 68/244 reads (28%) | called by muse, mutect2, varscan2
- SLC16A9 | c.555C>T p.G185= | Silent (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- SLC5A2 | c.501G>A p.Q167= | Silent (SNP) | VAF 48/788 reads (6%) | called by muse, mutect2
- SLC66A1 | c.703C>T p.L235= | Silent (SNP) | VAF 32/143 reads (22%) | catalogued as COSV100913356; called by muse, mutect2, varscan2
- SMARCA4 | c.4776C>A p.S1592= | Silent (SNP) | VAF 75/331 reads (23%) | catalogued as rs1292187087, COSV60794851; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMCR8 | c.2421G>A p.T807= | Silent (SNP) | VAF 77/249 reads (31%) | catalogued as rs768508672, COSV68811566; called by muse, mutect2, varscan2
- SNTA1 | c.1122C>T p.H374= | Silent (SNP) | VAF 23/416 reads (6%) | catalogued as rs887122815, COSV54128968; called by muse, mutect2
- SPHK1 | c.177C>T p.H59= (on ENST00000392496 / NM_001355139.2; = p.H73= on NM_021972.4) | Silent (SNP) | VAF 10/105 reads (10%) | catalogued as rs779438453; called by muse, mutect2, varscan2
- TAS2R60 | c.861G>C p.L287= | Silent (SNP) | VAF 16/310 reads (5%) | called by muse, mutect2
- TASOR2 | c.5037G>A p.V1679= | Silent (SNP) | VAF 82/292 reads (28%) | catalogued as rs372757738; called by muse, mutect2, varscan2
- TECTA | c.4134C>T p.Y1378= | Silent (SNP) | VAF 36/103 reads (35%) | catalogued as rs139303865; called by muse, mutect2, varscan2
- TENT5B | c.243G>A p.V81= | Silent (SNP) | VAF 85/471 reads (18%) | called by muse, mutect2, varscan2
- TG | c.4479T>C p.C1493= | Silent (SNP) | VAF 106/394 reads (27%) | called by muse, mutect2, varscan2
- TGOLN2 | c.180G>A p.P60= | Silent (SNP) | VAF 130/428 reads (30%) | catalogued as rs769576579, COSV56407011; called by muse, mutect2, varscan2
- TH | c.447C>A p.A149= (on ENST00000381178 / NM_199292.3; = p.A118= on NM_000360.4) | Silent (SNP) | VAF 116/393 reads (30%) | called by muse, mutect2, varscan2
- THAP7 | c.798G>A p.Q266= | Silent (SNP) | VAF 147/533 reads (28%) | called by muse, mutect2, varscan2
- THSD7A | c.3027T>C p.N1009= | Silent (SNP) | VAF 80/250 reads (32%) | called by muse, mutect2, varscan2
- TMEM229A | c.690C>T p.A230= | Silent (SNP) | VAF 41/174 reads (24%) | called by muse, mutect2, varscan2
- TMEM67 | c.924A>G p.Q308= | Silent (SNP) | VAF 45/118 reads (38%) | called by muse, mutect2, varscan2
- TNS1 | c.3321C>A p.T1107= | Silent (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- TPO | c.2655G>A p.S885= | Silent (SNP) | VAF 164/681 reads (24%) | catalogued as rs756050827, COSV61101520; called by muse, mutect2, varscan2
- TRANK1 | c.3069G>A p.R1023= | Silent (SNP) | VAF 23/199 reads (12%) | called by muse, mutect2, varscan2
- TRAPPC12 | c.888C>T p.T296= | Silent (SNP) | VAF 36/426 reads (8%) | catalogued as COSV60848108; called by muse, mutect2
- TREH | c.1122G>A p.T374= | Silent (SNP) | VAF 75/270 reads (28%) | catalogued as rs1470084512; called by muse, mutect2, varscan2
- TRPC7 | c.561C>T p.G187= | Silent (SNP) | VAF 34/107 reads (32%) | catalogued as COSV61457172; called by muse, mutect2, varscan2
- UBR3 | c.63G>A p.A21= | Silent (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- UNC79 | c.2289G>A p.P763= (on ENST00000393151 / NM_001346218.2; = p.P586= on NM_020818.5) | Silent (SNP) | VAF 22/444 reads (5%) | catalogued as rs140433326; called by muse, mutect2
- WDTC1 | c.357C>T p.H119= | Silent (SNP) | VAF 43/257 reads (17%) | catalogued as rs546300879; called by muse, mutect2, varscan2
- WNT8A | c.586C>T p.L196= | Silent (SNP) | VAF 23/301 reads (8%) | called by muse, mutect2
- YY2 | c.573C>T p.N191= | Silent (SNP) | VAF 9/199 reads (5%) | catalogued as rs959495609, COSV63412419; called by muse, mutect2
126 further variants in this file (0 protein-altering or splice-affecting, 11 silent, 115 other) are not listed here.
